TCGA case TCGA-HC-7232 — Prostate Adenocarcinoma (TCGA-PRAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Acinar Cell Neoplasms; Primary site: Prostate gland; Tissue source site: International Genomics Consortium. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ce3585d3-7388-4d05-84c8-64e0883003b3

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 66 years; Vital status: Alive.

Diagnoses (1)
1. Acinar cell carcinoma: ICD-O-3 morphology code: 8550/3; ICD-10 code: C61; Tissue or organ of origin: Prostate gland; Site of resection or biopsy: Prostate gland; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 66.6 years (24,324 days); Year of diagnosis: 2011; Method of diagnosis: Core Biopsy; AJCC pathologic T: T3b; Primary gleason grade: Pattern 4; Secondary gleason grade: Pattern 5; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Gleason score: 9.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 794 days (2.2 years); Days to treatment end: 851 days (2.3 years); Treatment dose: 7,020 cGy; Treatment outcome: Stable Disease; Number of fractions: 39; Treatment anatomic sites: Primary Tumor Field.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; Pharmaceutical Therapy, NOS, for biochemical recurrence.

Follow-up (3 entries)
- Days to follow up: 89 days; Disease response: Tumor Free.
- Day 766 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Biochemical; Days to recurrence: 766 days (2.1 years).
- Days to follow up: 1,161 days (3.2 years); Disease response: With Tumor.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-HC-7232-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1; Intermediate dimension: 0.6; Shortest dimension: 0.4.
  Slide TCGA-HC-7232-01A-01-TS1: Section location: Top; Percent tumor nuclei: 65; Percent necrosis: 0.
- Sample TCGA-HC-7232-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-HC-7232-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Prostate; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Histologic diagnosis: Prostate Adenocarcinoma Acinar Type; Method initial path diagnosis: Core needle biopsy; Lymph nodes examined: No.
- Stage record, Gleason grading: Gleason pattern primary: 4; Gleason pattern secondary: 5.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor; New tumor event diagnosis indicator: Yes; New tumor event type: Biochemical evidence of disease; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,161 days; disease-specific survival: no event (censored), 1,161 days; disease-free interval: event (new tumor event after initially disease-free), 766 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 766 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-HC-7232-01A-11D-2112-01): tumor purity 0.6, ploidy 1.95, whole-genome doublings 0.
